Gene-level copy-number profile of tumor specimen TCGA-23-1116-01A from TCGA case TCGA-23-1116, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 83.4 years (30,464 days).
Specimen TCGA-23-1116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f18ae0f5-b5bf-48d6-afb0-10a7c816c8fa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1116-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/836215af-b714-4695-a7fa-322211683644

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 863; copy number 2: 17,070; copy number 3: 21,055; copy number 4: 12,683; copy number 5: 4,476; copy number 6: 858; copy number 7: 94; copy number 8: 1,575; copy number 9: 294; copy number 11: 393; copy number 12: 33; copy number 13: 140; copy number 16: 22; copy number 19: 125; copy number 21: 22; copy number 22: 32; copy number 36: 46; copy number 44: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1116-01A-01D-0428-01): tumor purity 0.34, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,806 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,455,568–173,336,965, 135 genes, copy number 12–22 (within-gene range 12–23) (broad region; genes not listed).
- chr3:173,644,231–173,644,711, 1 gene, copy number 12: AC092967.1.
- chr4:68,182,292–75,724,589, 164 genes, copy number 7–9 (broad region; genes not listed).
- chr7:46,302,120–48,927,454, 30 genes, copy number 8–9: AC023669.2, AC004869.2, AC004869.1, HMGN1P19, AC011294.1, EPS15P1, AC004870.4, AC004870.2, AC004870.3, MRPL42P4, AC004870.1, AC087175.1, TNS3, LINC01447, C7orf65, PKD1L1, LINC00525, C7orf69, AC069282.1, HUS1, SUN3, C7orf57, UPP1, ABCA13, AC091770.1, LINC02838, AC004899.1, AC004899.2, GDI2P1, CDC14C.
- chr8:47,941,426–145,066,685, 1,495 genes, copy number 8–12 (broad region; genes not listed).
- chr11:68,460,731–73,142,318, 154 genes, copy number 8–11 (broad region; genes not listed).
- chr12:23,529,504–34,249,958, 217 genes, copy number 11–44 (broad region; genes not listed).
- chr19:29,083,094–40,740,860, 459 genes, copy number 8–21 (within-gene range 5–21) (broad region; genes not listed).
- chr21:33,915,534–33,977,691, 1 gene, copy number 8 (within-gene range 6–8): LINC00649.
- chr21:33,967,101–41,282,530, 150 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
